Gene-level copy-number profile of tumor specimen TCGA-BT-A42B-01A from TCGA case TCGA-BT-A42B, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 59.7 years (21,788 days).
Specimen TCGA-BT-A42B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.2fe4e215-9b90-41d6-bae9-cc8c7ee48609.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BT-A42B-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/651b5a4e-2c5d-46c9-8142-2758cf43f325

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 52; copy number 1: 16,148; copy number 2: 42,134; copy number 3: 1,482.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BT-A42B-01A-32D-A23L-01): tumor purity 0.78, ploidy 1.8, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 52 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:68,215,756–68,301,821, 1 gene (within-gene range 0–1): PIK3R1.
- chr5:111,223,653–111,494,886, 1 gene (within-gene range 0–1): CAMK4.
- chr5:111,496,033–111,739,726, 4 genes: STARD4, STARD4-AS1, HMGN1P13, AC008967.1.
- chr5:111,719,769–111,720,061, 1 gene: RN7SKP57.
- chr5:112,160,526–112,210,139, 4 genes: EPB41L4A-AS1, SNORA13, AC010261.1, AC010261.2.
- chr5:118,575,575–118,785,459, 5 genes: LINC02216, AC114311.1, LINC02215, RNU7-34P, AC093206.1.
- chr6:115,358,498–115,358,752, 1 gene: AL606845.1.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,929,457–22,824,213, 12 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.
- chr10:80,125,941–80,533,124, 15 genes (within-gene range 0–1): RPL22P18, PLAC9, ANXA11, LINC00857, RPS12P2, AL513174.1, EIF5AP4, AL359195.2, MAT1A, ZNF519P1, AL359195.1, DYDC1, DYDC2, PRXL2A, TSPAN14.
- chr10:124,867,510–124,988,189, 4 genes: NPM1P31, AL731577.2, ZRANB1, AL731577.1.
- chr10:124,996,064–125,001,491, 1 gene: AL731571.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 13,761. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
